Gene-level copy-number profile of tumor specimen TCGA-FG-5965-02B from TCGA case TCGA-FG-5965, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 39.0 years (14,249 days).
Specimen TCGA-FG-5965-02B: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.33c14457-aee0-42f4-8560-db93af55d878.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FG-5965-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 357 have no estimate.
https://portal.gdc.cancer.gov/files/f172db8e-4d6d-4c1a-9cea-8453c97eaf24

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 533; copy number 1: 192; copy number 2: 6,888; copy number 3: 18,724; copy number 4: 27,621; copy number 5: 3,375; copy number 6: 1,880; copy number 7: 480; copy number 8: 117; copy number 9: 65; copy number 10: 27; copy number 11: 104; copy number 12: 2; copy number 13: 3; copy number 14: 149; copy number 15: 2; copy number 17: 104.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–215,893, 9 genes: WASHC1, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, AL158832.2, DOCK8-AS1.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr11:5,776,165–5,783,355, 1 gene: OR52N5.
- chr15:76,586,647–76,586,691, 1 gene: MIR3713.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 456 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,832,189, 2 genes, copy number 15: CFHR3, CFHR1.
- chr15:20,379,495–22,282,872, 104 genes, copy number 17 (within-gene range 7–17) (broad region; genes not listed).
- chr17:58,192,726–62,627,590, 149 genes, copy number 14 (broad region; genes not listed).
- chr17:63,909,597–72,640,472, 182 genes, copy number 9–12 (within-gene range 6–12) (broad region; genes not listed).
- chr17:72,645,949–73,092,712, 1 gene, copy number 13 (within-gene range 6–13): SLC39A11.
- chr17:72,818,836–72,839,718, 2 genes, copy number 13: AC080037.1, AC011120.1.
- chr17:74,256,896–74,607,229, 16 genes, copy number 9: AC100786.1, DNAI2, AC103809.1, KIF19, BTBD17, GPR142, RNA5SP448, GPRC5C, CD300A, CD300LB, CD300C, AC079325.1, CD300H, CD300LD, C17orf77, AC064805.1.

Autosomal genes at a single copy (total copy number 1): 155. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
